Somatic mutation profile of tumor specimen TCGA-50-5946-01A (aliquot TCGA-50-5946-01A-11D-1753-08) from TCGA case TCGA-50-5946, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 62.6 years (22,852 days).
Specimen TCGA-50-5946-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 170e2745-2ad5-4403-9065-5a96121454f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-5946-10A (Blood Derived Normal), aliquot TCGA-50-5946-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc63c449-f591-4f97-9b72-4f52a103c464

The open-access MAF lists 718 somatic variants for this specimen: 534 protein-altering or splice-affecting, 169 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 461, Silent 169, Nonsense Mutation 35, Frame Shift Del 17, Splice Site 13, Intron 7, Frame Shift Ins 4, RNA 4, In Frame Del 2, 3'UTR 2, Splice Region 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1526G>T p.G509V (on ENST00000288602 / NM_001374244.1; = p.G469V on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 83/208 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CBL | c.1237G>C p.G413R | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs371679886, COSV50631517, COSV50635110; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NSD1 | c.6020T>C p.I2007T | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554204921, COSV61772206; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB8 | c.1615C>T p.R539C (on ENST00000297504 / NM_001282291.2; = p.R522C on NM_007188.5) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.302); catalogued as rs767522915, COSV99873809; called by muse, mutect2, varscan2
- ABTB1 | c.1338C>G p.H446Q (on ENST00000232744 / NM_172027.3; = p.H304Q on NM_032548.3) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51740351, COSV51740367; called by muse, mutect2, varscan2
- ADAMTS12 | c.2665G>T p.G889W | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61276406; called by muse, mutect2, varscan2
- ADAMTS3 | c.1745+1G>T p.X582_splice | Splice Site (SNP) | VAF 9/34 reads (26%) | catalogued as COSV54387112; called by muse, varscan2
- ADAMTSL1 | c.1717G>T p.A573S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.029); catalogued as COSV52810306; called by muse, mutect2, varscan2
- ADD2 | c.2121G>C p.K707N | Missense Mutation (SNP) | VAF 45/301 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); catalogued as COSV52456426; called by muse, mutect2, varscan2
- ADGRF2 | c.1336C>A p.L446M (on ENST00000296862 / NM_001368115.2; = p.L378M on NM_153839.7) | Missense Mutation (SNP) | VAF 33/250 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57287103; called by muse, mutect2, varscan2
- ADGRL2 | c.473C>A p.A158D | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as COSV54656881; called by muse, mutect2, varscan2
- AFM | c.472C>A p.L158I | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as rs1560409010, COSV56919059, COSV56919350; called by muse, mutect2, varscan2
- AGO1 | c.512+1G>T p.X171_splice | Splice Site (SNP) | VAF 9/68 reads (13%) | catalogued as COSV64594803; called by muse, mutect2, varscan2
- AHNAK2 | c.11665G>A p.V3889M | Missense Mutation (SNP) | VAF 99/326 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.835); catalogued as rs373615265, COSV60909964; called by muse, mutect2, varscan2
- AHNAK2 | c.11541G>C p.K3847N | Missense Mutation (SNP) | VAF 71/242 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV60909972; called by muse, mutect2, varscan2
- AIPL1 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51506185; called by muse, mutect2, varscan2
- AK8 | c.889G>T p.V297F | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV53751474; called by muse, mutect2, varscan2
- AKR1B15 | c.636G>T p.Q212H | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71151188; called by muse, mutect2, varscan2
- ALK | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 16/82 reads (20%) | catalogued as COSV66586819; called by muse, mutect2, varscan2
- ALOX12 | c.1795C>A p.R599S | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs757495245, COSV52348918, COSV52351528; called by muse, mutect2, varscan2
- AMACR | c.922C>T p.H308Y | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); catalogued as COSV56870238; called by muse, mutect2, varscan2
- ANGPTL5 | c.733G>T p.V245L | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as COSV57532216; called by muse, mutect2, varscan2
- ANK2 | c.11855C>T p.S3952L | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.544); catalogued as COSV99999805; called by muse, mutect2, varscan2
- ANKRD28 | c.2972C>G p.P991R | Missense Mutation (SNP) | VAF 58/185 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV67517226; called by muse, mutect2, varscan2
- ANKRD30A | c.995T>A p.V332E (on ENST00000611781; = p.V276E on NM_052997.2) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV64606072; called by muse, mutect2, varscan2
- ANO2 | c.2474T>A p.I825N (on ENST00000356134 / NM_001278597.3; = p.I829N on NM_001278596.3) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59011435; called by muse, mutect2
- ANO7 | c.1232T>A p.L411Q (on ENST00000274979; = p.L357Q on NM_001370694.2) | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.183); catalogued as COSV51469443; called by muse, mutect2, varscan2
- ANP32A | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as COSV51189383; called by muse, mutect2, varscan2
- ANXA3 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV53713734; called by muse, mutect2, varscan2
- APH1A | c.272A>G p.Y91C | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52528410; called by muse, mutect2
- APOBEC4 | c.982C>A p.Q328K | Missense Mutation (SNP) | VAF 19/270 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as COSV58017029; called by muse, mutect2
- ARHGAP33 | c.3115G>A p.G1039S | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); catalogued as rs561150729, COSV50119719; called by muse, mutect2, varscan2
- ARID5B | c.782G>T p.R261I | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54415908; called by muse, mutect2, varscan2
- ARMC3 | c.530T>A p.L177* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as COSV53058285; called by muse, mutect2, varscan2
- ARMC4 | c.2433A>T p.Q811H | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.665); catalogued as rs755790914, COSV59458695, COSV59468507; called by muse, mutect2, varscan2
- ARMCX1 | c.133A>G p.T45A | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV65704963; called by muse, mutect2
- ASAH1 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV50501508; called by muse, mutect2, varscan2
- ASH1L | c.6024G>C p.L2008F | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.986); catalogued as COSV64206265; called by muse, mutect2, varscan2
- ASPSCR1 | c.606G>T p.L202F | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.521); catalogued as COSV60727607; called by muse, mutect2, varscan2
- ATP10B | c.192G>C p.R64S | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as COSV58778046, COSV58778794; called by muse, mutect2, varscan2
- ATRNL1 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 84/195 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100746196, COSV61799218; called by muse, mutect2, varscan2
- ATRX | c.5911G>T p.D1971Y | Missense Mutation (SNP) | VAF 153/238 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV64872950, COSV64872993; called by muse, mutect2, varscan2
- AXDND1 | c.375G>T p.R125S | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62640535; called by muse, mutect2
- BCHE | c.1432C>A p.L478M | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); catalogued as COSV52254461; called by muse, mutect2, varscan2
- BEX2 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as COSV65500693; called by muse, mutect2, varscan2
- BIN2 | c.239G>A p.R80K | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.388); catalogued as COSV57207587; called by muse, mutect2, varscan2
- BLNK | c.328C>A p.P110T | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV56409502; called by muse, mutect2, varscan2
- BMI1 | c.356A>T p.D119V | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV64958785; called by muse, mutect2, varscan2
- BOD1L1 | c.692A>T p.E231V | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV50007852; called by muse, mutect2, varscan2
- BRCA2 | c.2290G>A p.E764K | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.149); catalogued as COSV66449983; called by muse, mutect2, varscan2
- C1orf116 | c.701C>G p.S234C | Missense Mutation (SNP) | VAF 47/270 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.195); catalogued as COSV63943827; called by muse, mutect2, varscan2
- C2orf16 | c.772C>A p.Q258K | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV68645504; called by muse, mutect2, varscan2
- C4orf17 | c.532G>T p.D178Y | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV58511134, COSV58513402; called by muse, mutect2
- C4orf3 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs775986774, COSV101208163, COSV67581580; called by muse, mutect2, varscan2
- C8B | c.945C>A p.Y315* | Nonsense Mutation (SNP) | VAF 10/57 reads (18%) | catalogued as COSV100980718, COSV64776734; called by muse, mutect2, varscan2
- C9 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 102/213 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54675037; called by muse, mutect2, varscan2
- CABP1 | c.724G>A p.D242N (on ENST00000316803 / NM_001033677.1; = p.D39N on NM_004276.5) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV56457819; called by muse, mutect2, varscan2
- CALD1 | c.1466C>A p.T489K (on ENST00000361675 / NM_033138.4; = p.T234K on NM_004342.7) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.602); catalogued as COSV62645877; called by muse, mutect2, varscan2
- CARD6 | c.1948G>T p.A650S | Missense Mutation (SNP) | VAF 165/387 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV54564783; called by muse, mutect2, varscan2
- CARMIL3 | c.1874A>G p.H625R | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV57725363; called by muse, mutect2, varscan2
- CASS4 | c.1722G>T p.K574N | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64385649; called by muse, mutect2, varscan2
- CATSPERE | c.612G>T p.Q204H | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63676664; called by muse, mutect2, varscan2
- CCDC40 | c.1290C>G p.I430M | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53897687; called by muse, mutect2, varscan2
- CCDC54 | c.971_973del p.E324del | In Frame Del (DEL) | VAF 10/76 reads (13%) | catalogued as rs778479927; called by pindel, varscan2
- CCDC9B | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.297); catalogued as COSV66874899, COSV66875744; called by muse, mutect2, varscan2
- CD34 | c.292G>T p.V98L | Missense Mutation (SNP) | VAF 51/251 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV60412071; called by muse, mutect2, varscan2
- CD4 | c.956-2A>T p.X319_splice | Splice Site (SNP) | VAF 18/56 reads (32%) | catalogued as COSV50589386; called by muse, mutect2, varscan2
- CDH12 | c.2131A>C p.T711P | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.378); catalogued as COSV66392964; called by muse, mutect2, varscan2
- CDH12 | c.568C>A p.P190T | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66392968; called by muse, mutect2
- CDH4 | c.2098C>G p.L700V | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.687); catalogued as COSV64644752; called by muse, mutect2, varscan2
- CENPF | c.4541G>T p.G1514V | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as COSV65273258; called by muse, mutect2, varscan2
- CEP192 | c.3700C>T p.H1234Y | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1336741406, COSV58061107; called by muse, mutect2, varscan2
- CFAP100 | c.743G>C p.R248T | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as COSV61502562; called by muse, mutect2, varscan2
- CFAP47 | c.4466G>T p.G1489V | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV57971969; called by muse, mutect2, varscan2
- CFAP58 | c.2342G>T p.R781L | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as COSV63833041; called by muse, mutect2, varscan2
- CFAP61 | c.952-1G>T p.X318_splice | Splice Site (SNP) | VAF 24/78 reads (31%) | catalogued as COSV55622107; called by muse, mutect2, varscan2
- CFAP61 | c.2111C>A p.P704Q | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55622130; called by muse, mutect2, varscan2
- CFH | c.2158T>A p.S720T | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.03); catalogued as COSV66406597; called by muse, mutect2, varscan2
- CHD6 | c.8138A>T p.D2713V | Missense Mutation (SNP) | VAF 17/209 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV64688884; called by muse, mutect2
- CHMP4B | c.483+1G>T p.X161_splice | Splice Site (SNP) | VAF 17/85 reads (20%) | catalogued as COSV54135344, COSV54137952; called by muse, mutect2, varscan2
- CHRNA4 | c.970A>G p.T324A | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV64718720; called by muse, mutect2, varscan2
- CLDN10 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV54823530; called by muse, mutect2, varscan2
- CLIP4 | c.1823G>T p.W608L | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as COSV60748066; called by muse, mutect2, varscan2
- CNDP2 | c.1001G>T p.R334M | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as COSV100158907; called by muse, mutect2
- CNGA1 | c.1657G>T p.A553S | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV62053341; called by muse, mutect2
- CNKSR2 | c.88T>C p.Y30H | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54251113; called by muse, mutect2, varscan2
- CNOT3 | c.387G>C p.T129= | Splice Region (SNP) | VAF 5/25 reads (20%) | catalogued as COSV55361055; called by muse, mutect2, varscan2
- CNPY1 | c.118G>T p.D40Y | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58786813; called by muse, mutect2, varscan2
- CNTNAP4 | c.1525C>G p.L509V | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs1326923896, COSV56669182; called by muse, mutect2, varscan2
- CNTNAP5 | c.1631G>A p.C544Y | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70477372, COSV70508717; called by muse, mutect2, varscan2
- COL24A1 | c.2141G>T p.G714V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs894949609, COSV65303270; called by muse, mutect2, varscan2
- COL3A1 | c.3589T>A p.C1197S | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.169); catalogued as COSV58583839; called by muse, mutect2, varscan2
- COL4A6 | c.3305T>A p.I1102K | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.95); PolyPhen benign (0.02); catalogued as COSV57860868; called by muse, mutect2, varscan2
- COL9A1 | c.1165C>A p.P389T | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV57880396; called by muse, mutect2, varscan2
- COX7B2 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs373085380; called by muse, mutect2, varscan2
- CPD | c.2089G>A p.D697N | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as COSV56711328; called by muse, mutect2, varscan2
- CRYBG1 | c.2269G>T p.E757* | Nonsense Mutation (SNP) | VAF 14/88 reads (16%) | catalogued as COSV64811158, COSV64812480; called by muse, mutect2, varscan2
- CSMD2 | c.3172G>T p.G1058C | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53888507; called by muse, mutect2, varscan2
- CSMD3 | c.354C>A p.Y118* | Nonsense Mutation (SNP) | VAF 59/102 reads (58%) | catalogued as COSV52125086; called by muse, mutect2, varscan2
- CSTA | c.114G>C p.L38F | Missense Mutation (SNP) | VAF 28/221 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52611858; called by muse, mutect2, varscan2
- CTNNA3 | c.1406G>C p.R469T | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV65560596; called by muse, mutect2, varscan2
- CWH43 | c.2062C>A p.H688N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56936884; called by muse, mutect2, varscan2
- CYP4F3 | c.1522del p.A508Qfs*12 | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | catalogued as COSV99657896; called by mutect2, pindel, varscan2
- DDR2 | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63369852; called by muse, mutect2, varscan2
- DDR2 | c.757G>A p.G253S | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376303676; called by muse, mutect2, varscan2
- DDX11 | c.1210G>T p.G404C | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV52501020, COSV99300511; called by muse, mutect2, varscan2
- DIO1 | c.609C>A p.N203K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59518764; called by muse, mutect2, varscan2
- DMXL1 | c.3248G>T p.C1083F | Missense Mutation (SNP) | VAF 42/217 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60706472; called by muse, mutect2, varscan2
- DNAH2 | c.9951C>G p.F3317L | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV66717469; called by muse, mutect2, varscan2
- DNAH5 | c.8128G>T p.G2710C | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54210217; called by muse, mutect2, varscan2
- DNAH8 | c.3469G>T p.V1157L | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV59431290; called by muse, mutect2, varscan2
- DNAH9 | c.1798G>T p.V600L | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated (0.99); PolyPhen benign (0.006); catalogued as COSV52339304; called by muse, mutect2, varscan2
- DNAH9 | c.13421A>T p.K4474M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52339314; called by muse, mutect2, varscan2
- DNAI4 | c.2365G>T p.A789S | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV64028422; called by muse, mutect2, varscan2
- DNAJC14 | c.170C>G p.S57C | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.671); catalogued as COSV57912422; called by muse, mutect2, varscan2
- DOK5 | c.571A>G p.T191A | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770109660, COSV52817686; called by muse, mutect2, varscan2
- DOP1A | c.2338A>G p.T780A | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV52707794; called by muse, mutect2, varscan2
- DPYD | c.1369A>T p.N457Y | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV64592822; called by muse, mutect2, varscan2
- DPYS | c.670G>T p.A224S | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV60907178; called by muse, mutect2, varscan2
- DSCAML1 | c.3712C>A p.R1238S (on ENST00000321322; = p.R1178S on NM_020693.4) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.274); catalogued as COSV58384456, COSV58394794; called by muse, mutect2, varscan2
- DST | c.15542G>C p.R5181P (on ENST00000361203 / NM_001374722.1; = p.R2769P on NM_015548.5) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55002147; called by muse, mutect2, varscan2
- DYSF | c.1437C>A p.Y479* | Nonsense Mutation (SNP) | VAF 32/84 reads (38%) | catalogued as COSV50277477; called by muse, mutect2, varscan2
- DYSF | c.2884G>A p.G962R | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs151064013, COSV50277551; ClinVar: uncertain significance; called by mutect2, varscan2
- DZANK1 | c.1048G>T p.A350S (on ENST00000262547 / NM_001099407.1; = p.A151S on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV52748592; called by muse, mutect2, varscan2
- EHHADH | c.954G>T p.R318S | Missense Mutation (SNP) | VAF 79/171 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV51628391; called by muse, mutect2, varscan2
- EIF2AK3 | c.2960C>A p.T987N | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57545695; called by muse, mutect2, varscan2
- EIF4G1 | c.1948C>T p.R650W (on ENST00000346169 / NM_198241.3; = p.R454W on NM_004953.5) | Missense Mutation (SNP) | VAF 89/183 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs969580781, COSV59989637; called by muse, mutect2, varscan2
- EPHB1 | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs576710309, COSV101213156, COSV67655893; called by mutect2, varscan2
- EPM2AIP1 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.522); catalogued as COSV51615367; called by muse, mutect2, varscan2
- ERCC3 | c.1843T>C p.F615L | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as COSV53426037; called by muse, mutect2, varscan2
- ERRFI1 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV66310432; called by muse, mutect2, varscan2
- EXOC7 | c.632G>C p.R211P | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.901); catalogued as COSV58739932, COSV58741315; called by muse, mutect2, varscan2
- EXPH5 | c.4034A>T p.Q1345L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.222); catalogued as COSV56199688; called by muse, mutect2, varscan2
- EYS | c.1076C>A p.S359* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as COSV60979157; called by muse, mutect2, varscan2
- F8 | c.1798G>T p.E600* | Nonsense Mutation (SNP) | VAF 48/195 reads (25%) | catalogued as CM0911112, CM123900, CM990547, COSV100811991, COSV64270472; called by muse, mutect2, varscan2
- FAIM2 | c.214A>T p.S72C | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.124); catalogued as COSV57738166; called by muse, mutect2
- FAM13C | c.1613A>T p.Q538L | Missense Mutation (SNP) | VAF 23/248 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV53244722; called by muse, mutect2
- FAM171A1 | c.439G>T p.V147F | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs746749391, COSV65314260; called by muse, mutect2, varscan2
- FAM9B | c.182-1G>T p.X61_splice | Splice Site (SNP) | VAF 6/11 reads (55%) | catalogued as COSV59119189; called by muse, varscan2
- FAR2 | c.686C>A p.P229H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51729202; called by muse, mutect2, varscan2
- FAT2 | c.2459T>A p.F820Y | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55815244; called by muse, mutect2, varscan2
- FAT3 | c.4073T>C p.I1358T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV53086459; called by muse, mutect2, varscan2
- FBN2 | c.6762C>G p.I2254M | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.708); catalogued as COSV52498318, COSV52498761; called by muse, mutect2, varscan2
- FBXO4 | c.1063C>T p.H355Y | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.139); catalogued as COSV55851547; called by muse, mutect2
- FGB | c.425C>G p.S142C | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV57417703, COSV57417883; called by muse, mutect2, varscan2
- FGF7 | c.83T>C p.I28T | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV51065647; called by muse, mutect2, varscan2
- FH | c.1165G>T p.G389W | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63817698; called by muse, mutect2
- FOCAD | c.8A>G p.D3G | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV58095139; called by muse, mutect2, varscan2
- FOXC2 | c.364C>A p.H122N | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57445605; called by muse, mutect2, varscan2
- FSCB | c.189G>T p.K63N | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61217048, COSV61219539; called by muse, mutect2, varscan2
- FSHB | c.33T>A p.C11* | Nonsense Mutation (SNP) | VAF 38/74 reads (51%) | catalogued as COSV54221470; called by muse, mutect2, varscan2
- FXYD5 | c.28C>G p.L10V | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as COSV54342200; called by muse, mutect2, varscan2
- GAD2 | c.853C>T p.L285F | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV52152251; called by mutect2, varscan2
- GADL1 | c.724G>T p.D242Y | Missense Mutation (SNP) | VAF 101/275 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56976083, COSV56978021; called by muse, mutect2, varscan2
- GATA3 | c.918del p.R306Sfs*49 | Frame Shift Del (DEL) | VAF 25/72 reads (35%) | catalogued as COSV60522371; called by mutect2, pindel, varscan2
- GBF1 | c.2106+1G>T p.X702_splice (on ENST00000369983 / NM_001377137.1; = p.X701_splice on NM_004193.3) | Splice Site (SNP) | VAF 48/119 reads (40%) | catalogued as COSV64148471; called by muse, mutect2, varscan2
- GLI3 | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.757); catalogued as rs769783770, COSV67886171; called by muse, mutect2, varscan2
- GOLGA2 | c.108G>C p.K36N | Missense Mutation (SNP) | VAF 160/362 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as COSV60791730; called by muse, mutect2, varscan2
- GOLGB1 | c.3681G>T p.E1227D | Missense Mutation (SNP) | VAF 46/270 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as COSV61462785; called by muse, mutect2, varscan2
- GPD2 | c.738C>A p.Y246* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as COSV60096320; called by muse, mutect2, varscan2
- GPNMB | c.1172A>G p.N391S (on ENST00000381990 / NM_001005340.2; = p.N379S on NM_002510.3) | Missense Mutation (SNP) | VAF 41/313 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV51697333; called by muse, mutect2, varscan2
- GPR101 | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.031); catalogued as rs747548759, COSV53237794; called by muse, mutect2, varscan2
- GPR174 | c.413G>T p.S138I | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52131744; called by muse, mutect2, varscan2
- GPR4 | c.131G>C p.R44P | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV59916303, COSV59916377; called by muse, mutect2, varscan2
- GPR85 | c.772G>T p.G258C | Missense Mutation (SNP) | VAF 57/197 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51782998; called by muse, mutect2, varscan2
- GPRIN3 | c.2020C>T p.Q674* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as rs1327588570, COSV60884365; called by muse, mutect2, varscan2
- GRAMD4 | c.762C>A p.F254L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as COSV63032157; called by muse, mutect2
- GRIK4 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as COSV70800662; called by muse, mutect2, varscan2
- GRM7 | c.61C>G p.L21V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.899); catalogued as COSV63133846; called by muse, mutect2, varscan2
- GTPBP4 | c.95C>A p.T32N | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62550331; called by muse, mutect2, varscan2
- GUCA1C | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 44/132 reads (33%) | catalogued as COSV99225113; called by muse, mutect2, varscan2
- GUCA1C | c.84G>T p.M28I | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99225116, COSV99227352; called by muse, mutect2, varscan2
- GUCY1A2 | c.1651A>C p.T551P | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56480500; called by muse, mutect2, varscan2
- GUCY1A2 | c.1267G>T p.G423C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56480516; called by muse, mutect2, varscan2
- H2BC9 | c.307C>G p.L103V | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as COSV55099510, COSV99079196; called by muse, mutect2, varscan2
- H3C3 | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV63550736; called by muse, mutect2, varscan2
- HAO1 | c.752G>A p.G251D | Missense Mutation (SNP) | VAF 69/131 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as COSV66491374; called by muse, mutect2, varscan2
- HCK | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.342); catalogued as rs768447790, COSV52940932; called by muse, mutect2, varscan2
- HCRTR2 | c.1057G>T p.V353L | Missense Mutation (SNP) | VAF 68/191 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as rs76232306; called by muse, mutect2, varscan2
- HDAC9 | c.1027G>C p.A343P | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.462); catalogued as COSV67769159; called by muse, mutect2
- HEPHL1 | c.2402G>A p.R801Q | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs200108606, COSV59890083; called by muse, mutect2, varscan2
- HERC1 | c.722C>T p.T241I | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV71246597; called by muse, mutect2, varscan2
- HERC2 | c.11512G>T p.G3838C | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV55312337; called by muse, mutect2, varscan2
- HERC4 | c.1822G>T p.G608* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as COSV53269124; called by muse, mutect2, varscan2
- HIVEP1 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 13/255 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV65099489; called by muse, mutect2
- HK1 | c.1151A>G p.N384S | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as COSV53854949; called by muse, mutect2, varscan2
- HLA-G | c.763G>T p.V255L | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.166); catalogued as COSV64405247, COSV64405301; called by muse, mutect2, varscan2
- HMCN1 | c.6890G>T p.S2297I | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.424); catalogued as COSV54884187; called by muse, mutect2, varscan2
- HNF4A | c.1252T>A p.C418S | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated, low confidence (0.33); PolyPhen probably damaging (0.966); catalogued as COSV57380592; called by muse, mutect2
- HNRNPA1 | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV52935912; called by muse, mutect2, varscan2
- HOXA9 | c.344C>G p.T115R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1370995506, COSV100604268, COSV58655853; called by muse, mutect2, varscan2
- HOXB4 | c.672del p.N225Tfs*44 | Frame Shift Del (DEL) | VAF 20/100 reads (20%) | catalogued as COSV60178724; called by mutect2, pindel, varscan2
- HPN | c.447C>G p.I149M | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as COSV52882524; called by muse, mutect2, varscan2
- HPS5 | c.2461G>T p.V821L (on ENST00000349215 / NM_181507.2; = p.V707L on NM_007216.4) | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.132); catalogued as rs373228021; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HSPA8 | c.475A>G p.K159E | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as COSV57083035; called by muse, mutect2, varscan2
- HTR3A | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.642); catalogued as rs747021831, COSV55468362; called by muse, mutect2, varscan2
- ICE1 | c.2098G>A p.E700K | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV56820801; called by muse, mutect2, varscan2
- IFRD1 | c.846G>A p.M282I | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as rs764321257, COSV50043760; called by muse, mutect2, varscan2
- IGF2R | c.5070C>G p.F1690L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.832); catalogued as COSV63627027; called by muse, mutect2, varscan2
- IKZF1 | c.497T>A p.L166Q | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58782725; called by muse, mutect2, varscan2
- INSYN1 | c.749C>A p.S250* | Nonsense Mutation (SNP) | VAF 19/79 reads (24%) | catalogued as COSV65837233; called by muse, mutect2, varscan2
- IQSEC1 | c.1273G>T p.G425C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.735); catalogued as rs746716911, COSV56221927; called by muse, mutect2, varscan2
- KANK4 | c.531G>C p.E177D | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV62985759; called by mutect2, varscan2
- KCNB2 | c.502G>C p.D168H | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV73048885, COSV73049315; called by muse, mutect2, varscan2
- KCNIP3 | c.479G>C p.R160P | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54672242; called by muse, mutect2, varscan2
- KCNJ4 | c.127A>G p.M43V | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV57856429; called by muse, mutect2, varscan2
- KCNQ2 | c.2347G>T p.D783Y (on ENST00000359125 / NM_172107.4; = p.D755Y on NM_004518.6) | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV60553191, COSV60554313; called by muse, mutect2, varscan2
- KCNQ5 | c.451G>C p.E151Q | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.41); catalogued as COSV59647761, COSV59652822; called by muse, mutect2, varscan2
- KHDRBS2 | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.05); catalogued as COSV55434527; called by muse, mutect2, varscan2
- KIAA0753 | c.1237G>C p.E413Q | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV63816935; called by muse, varscan2
- KIAA0753 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.23); catalogued as COSV63816938; called by muse, varscan2
- KIAA1841 | c.1430C>T p.S477F | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.054); catalogued as COSV54373563; called by muse, mutect2, varscan2
- KIDINS220 | c.3118G>T p.V1040L | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.063); catalogued as COSV56751209; called by muse, varscan2
- KIF16B | c.1768A>T p.M590L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.869); catalogued as COSV61702550; called by muse, mutect2
- KIF23 | c.2491G>A p.E831K (on ENST00000260363; = p.E727K on NM_004856.7) | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as COSV52977919; called by muse, mutect2, varscan2
- KMT2C | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV51405289; called by muse, mutect2, varscan2
- KMT2E | c.1041A>T p.K347N | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV57570657; called by muse, mutect2
- KMT5B | c.1747C>G p.P583A | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV58564290, COSV58564418, COSV58566347; called by muse, mutect2, varscan2
- KMT5B | c.1655C>G p.S552C | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs1307058162, COSV58564431; called by muse, mutect2, varscan2
- KNL1 | c.5638A>G p.I1880V (on ENST00000346991 / NM_170589.5; = p.I1854V on NM_144508.5) | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as COSV61152280; called by muse, mutect2, varscan2
- KPRP | c.449T>G p.V150G | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV64221181; called by muse, mutect2, varscan2
- KRT15 | c.1367T>C p.I456T | Missense Mutation (SNP) | VAF 27/270 reads (10%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV54178499; called by muse, mutect2
- KRTAP24-1 | c.244A>T p.S82C | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.963); catalogued as COSV61089122; called by muse, mutect2, varscan2
- L1CAM | c.289A>G p.I97V | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.461); catalogued as COSV62827245; called by muse, mutect2, varscan2
- L2HGDH | c.506A>T p.Q169L | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.102); catalogued as COSV55556456; called by muse, mutect2, varscan2
- L3MBTL1 | c.1327G>T p.A443S (on ENST00000418998 / NM_001377303.1; = p.A353S on NM_015478.7) | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64228042; called by muse, mutect2, varscan2
- LAMA4 | c.1045C>A p.L349I (on ENST00000230538 / NM_001105206.3; = p.L342I on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as COSV57893095; called by muse, mutect2, varscan2
- LAMB3 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs139547896; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMC1 | c.1645G>T p.V549L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV51134251, COSV51147113; called by muse, mutect2, varscan2
- LAMP1 | c.1003T>C p.S335P | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58149042; called by muse, mutect2, varscan2
- LANCL2 | c.247G>C p.D83H | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV54648168; called by muse, mutect2, varscan2
- LCE3D | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.339); catalogued as rs201921868, COSV64230604; called by muse, mutect2
- LCLAT1 | c.625+1G>A p.X209_splice | Splice Site (SNP) | VAF 52/123 reads (42%) | catalogued as COSV58370982; called by muse, mutect2, varscan2
- LIPN | c.1091A>T p.Y364F | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.096); catalogued as COSV68383776; called by mutect2, varscan2
- LMCD1 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 38/225 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.713); catalogued as COSV50087561; called by muse, mutect2, varscan2
- LPO | c.1776G>A p.M592I | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1299546610, COSV51857364; called by muse, mutect2, varscan2
- LPP | c.527A>G p.K176R | Missense Mutation (SNP) | VAF 103/221 reads (47%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.699); catalogued as COSV57082324; called by muse, mutect2, varscan2
- LRP1B | c.12761G>A p.S4254N | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1375389625, COSV67196522; called by muse, mutect2, varscan2
- LRP1B | c.2564G>C p.R855T | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV63341633, COSV63341648; called by muse, mutect2, varscan2
- LRRC28 | c.552G>T p.E184D | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.352); catalogued as COSV57336276; called by muse, mutect2, varscan2
- LRRIQ1 | c.4189A>G p.K1397E | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.072); catalogued as COSV67827171; called by muse, mutect2, varscan2
- LRRN3 | c.595C>A p.P199T | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); catalogued as COSV100067970; called by muse, mutect2, varscan2
- LY75 | c.3528G>T p.W1176C | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99715991; called by muse, mutect2, varscan2
- LY75 | c.3527G>T p.W1176L | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759824829, COSV99715993; called by muse, mutect2, varscan2
- LY9 | c.1223G>A p.G408E | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.985); catalogued as COSV54432195; called by muse, mutect2, varscan2
- MAGEA4 | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV52340566; called by muse, mutect2, varscan2
- MAGEB4 | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as COSV100854788, COSV64396813; called by muse, mutect2, varscan2
- MAGEC1 | c.1612G>T p.E538* | Nonsense Mutation (SNP) | VAF 58/188 reads (31%) | catalogued as COSV53569466, COSV53580714; called by muse, mutect2, varscan2
- MAGEC2 | c.392C>A p.P131Q | Missense Mutation (SNP) | VAF 67/116 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.269); catalogued as COSV99909399; called by muse, mutect2, varscan2
- MAGEC2 | c.391C>A p.P131T | Missense Mutation (SNP) | VAF 66/115 reads (57%) | SIFT tolerated (0.5); PolyPhen benign (0.082); catalogued as COSV99909401; called by muse, mutect2, varscan2
- MAGEL2 | c.3190C>A p.R1064S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.274); catalogued as rs551493054, COSV58566263; called by muse, mutect2, varscan2
- MAGI2 | c.81G>T p.Q27H | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV62639838; called by muse, mutect2, varscan2
- MAP3K13 | c.2797G>T p.E933* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV53985061, COSV53995973; called by muse, mutect2, varscan2
- MCM5 | c.264G>T p.L88F | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV53345330; called by muse, mutect2, varscan2
- MCPH1 | c.1648G>C p.E550Q | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.088); catalogued as COSV60911127, COSV60915579; called by muse, mutect2, varscan2
- MEI1 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV55900858; called by muse, mutect2, varscan2
- METAP1D | c.604T>C p.C202R | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs940433921, COSV59929133; called by muse, mutect2, varscan2
- MFN2 | c.1618G>C p.D540H | Missense Mutation (SNP) | VAF 43/205 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52420879; called by muse, mutect2, varscan2
- MGAT4C | c.1108G>T p.G370W | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59830747; called by muse, mutect2, varscan2
- MIGA1 | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.733); catalogued as rs146380219; called by muse, mutect2, varscan2
- MMRN1 | c.263C>G p.T88R | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.282); catalogued as rs774290536, COSV53334836; called by mutect2, varscan2
- MNDA | c.523C>A p.L175I | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV63740166; called by muse, mutect2, varscan2
- MOV10L1 | c.1363G>T p.A455S | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as COSV53168365; called by muse, mutect2, varscan2
- MRC2 | c.1915C>T p.R639W | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs754790541, COSV57637568; called by muse, mutect2, varscan2
- MROH1 | c.828G>T p.K276N | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100395557; called by muse, mutect2
- MRPL38 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 7/15 reads (47%) | catalogued as COSV58614160; called by muse, mutect2, varscan2
- MRPS15 | c.306G>C p.E102D | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs774276263, COSV100910638, COSV64152197; called by muse, mutect2
- MRPS30 | c.748-1G>T p.X250_splice | Splice Site (SNP) | VAF 20/120 reads (17%) | catalogued as COSV50181560; called by muse, varscan2
- MST1R | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 23/93 reads (25%) | catalogued as rs1216259052, COSV56565834; called by muse, mutect2, varscan2
- MUC16 | c.17657G>C p.W5886S | Missense Mutation (SNP) | VAF 33/207 reads (16%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); catalogued as COSV67452251; called by muse, mutect2, varscan2
- MUC17 | c.389C>A p.P130H | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.612); catalogued as COSV60282508; called by muse, varscan2
- MYBL2 | c.129G>T p.R43S | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV53828395; called by muse, mutect2, varscan2
- MYH11 | c.1017C>A p.S339R | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV55545934; called by muse, mutect2, varscan2
- MYH2 | c.5669A>T p.E1890V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV55433373; called by muse, mutect2, varscan2
- MYH2 | c.2094G>C p.Q698H | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55433387, COSV99820543; called by muse, mutect2, varscan2
- MYH3 | c.3182A>T p.K1061M | Missense Mutation (SNP) | VAF 57/113 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV56862115; called by muse, mutect2, varscan2
- MYH8 | c.3049G>T p.E1017* | Nonsense Mutation (SNP) | VAF 25/162 reads (15%) | catalogued as COSV67961304; called by muse, mutect2, varscan2
- MYH8 | c.464C>A p.P155H | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101238771, COSV67961308; called by muse, mutect2, varscan2
- MYH9 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53383099; called by muse, mutect2, varscan2
- MYLIP | c.1028A>G p.N343S | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV62766458; called by muse, mutect2, varscan2
- MYO16 | c.2086C>G p.Q696E | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.42); catalogued as COSV51781881; called by muse, mutect2, varscan2
- MYO6 | c.3530A>T p.Q1177L (on ENST00000369981; = p.Q1167L on NM_004999.4) | Missense Mutation (SNP) | VAF 51/91 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.66); catalogued as COSV64117985; called by muse, mutect2, varscan2
- MYO9B | c.1146G>C p.E382D | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV68277664; called by muse, mutect2, varscan2
- MYOZ3 | c.15G>C p.E5D | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.887); catalogued as COSV51739094; called by muse, mutect2, varscan2
- MYT1L | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); catalogued as rs1429316688, COSV67712384; called by muse, mutect2, varscan2
- N6AMT1 | c.244G>C p.A82P | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58133925; called by muse, mutect2, varscan2
- NALCN | c.26G>A p.R9K | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV51923142; called by muse, mutect2, varscan2
- NAMPT | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.994); catalogued as COSV104383065, COSV55994457; called by muse, mutect2, varscan2
- NAV2 | c.3262G>T p.G1088* (on ENST00000396087 / NM_001244963.2; = p.G1065* on NM_145117.5) | Nonsense Mutation (SNP) | VAF 16/35 reads (46%) | catalogued as COSV60657215; called by muse, mutect2, varscan2
- NCAM1 | c.1490A>G p.Q497R (on ENST00000316851 / NM_181351.5; = p.Q487R on NM_000615.7) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV57512317; called by muse, mutect2, varscan2
- NCAN | c.2407G>T p.G803* | Nonsense Mutation (SNP) | VAF 14/128 reads (11%) | catalogued as COSV53047908; called by muse, mutect2, varscan2
- NCKAP1L | c.2041C>A p.L681I | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as COSV53204395; called by muse, mutect2, varscan2
- NCOA1 | c.4066-1G>C p.X1356_splice | Splice Site (SNP) | VAF 40/346 reads (12%) | catalogued as COSV56040494; called by muse, mutect2, varscan2
- NCOA2 | c.479A>G p.Y160C | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV71763653; called by muse, mutect2, varscan2
- NCOR2 | c.5187A>T p.R1729= | Splice Region (SNP) | VAF 30/78 reads (38%) | catalogued as COSV100656876; called by muse, mutect2, varscan2
- NCOR2 | c.5186G>T p.R1729L | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV100656877; called by muse, mutect2, varscan2
- NCR1 | c.682G>T p.A228S | Missense Mutation (SNP) | VAF 89/171 reads (52%) | SIFT tolerated (0.92); PolyPhen benign (0.023); catalogued as COSV52555784; called by muse, varscan2
- NEB | c.18505G>A p.E6169K | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1559338128, COSV50846166; called by muse, mutect2, varscan2
- NEB | c.9458G>T p.W3153L | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs1465012496, COSV50846379; called by muse, mutect2, varscan2
- NID1 | c.260C>A p.P87H | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1261570214, COSV51616285; called by muse, mutect2
- NIN | c.3715G>C p.E1239Q | Missense Mutation (SNP) | VAF 44/243 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55383036; called by muse, mutect2, varscan2
- NLRP12 | c.1747G>T p.V583F | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.107); catalogued as COSV60744549; called by muse, mutect2, varscan2
- NMD3 | c.574C>T p.H192Y | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as COSV63618303; called by muse, mutect2, varscan2
- NMNAT2 | c.43G>T p.G15C | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55078068, COSV99818059; called by muse, varscan2
- NMT1 | c.138G>C p.L46F | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.063); catalogued as COSV51958705; called by muse, mutect2
- NOBOX | c.674C>A p.S225* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as COSV56192900, COSV56193034; called by muse, mutect2, varscan2
- NOL6 | c.3334G>T p.E1112* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as COSV53039868; called by muse, mutect2, varscan2
- NOS1 | c.3647G>C p.C1216S | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57608281; called by muse, mutect2, varscan2
- NOTCH2 | c.2970G>C p.E990D | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV56684747; called by muse, mutect2
- NPAP1 | c.2020C>G p.P674A | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs901343402, COSV61505232, COSV61507875; called by muse, mutect2, varscan2
- NPY | c.234G>T p.L78F | Missense Mutation (SNP) | VAF 23/221 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.448); catalogued as COSV54214452, COSV54214761; called by muse, mutect2, varscan2
- NPY2R | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV61527505; called by muse, mutect2, varscan2
- NTNG1 | c.1150T>C p.C384R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV64268476; called by muse, mutect2, varscan2
- NTS | c.473G>T p.R158I | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55455641; called by muse, mutect2, varscan2
- NUCKS1 | c.220C>T p.H74Y | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.888); catalogued as COSV65652585; called by muse, mutect2, varscan2
- OBI1 | c.291A>T p.K97N | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV56144824; called by muse, mutect2, varscan2
- OLAH | c.626G>T p.G209V (on ENST00000378228 / NM_001039702.3; = p.G262V on NM_018324.3) | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65491747; called by muse, mutect2, varscan2
- OR10G7 | c.383C>A p.P128Q | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57866035; called by muse, mutect2
- OR13A1 | c.801C>A p.C267* | Nonsense Mutation (SNP) | VAF 21/57 reads (37%) | catalogued as COSV65572087; called by muse, mutect2, varscan2
- OR13F1 | c.317C>A p.A106D | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100594681; called by muse, mutect2, varscan2
- OR13G1 | c.710C>A p.T237K | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62943629; called by muse, mutect2, varscan2
- OR14A16 | c.415T>A p.C139S | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV62926250; called by muse, mutect2, varscan2
- OR2B3 | c.35T>C p.F12S | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65850783, COSV65850910; called by muse, mutect2, varscan2
- OR2L13 | c.318G>T p.M106I | Missense Mutation (SNP) | VAF 46/310 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV63549550; called by muse, mutect2, varscan2
- OR2M2 | c.122del p.G41Efs*90 | Frame Shift Del (DEL) | VAF 42/380 reads (11%) | catalogued as COSV62897771; called by mutect2, varscan2
- OR2T33 | c.245A>G p.D82G | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV58814567; called by muse, mutect2
- OR2T8 | c.245A>G p.D82G | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV60661826; called by muse, mutect2, varscan2
- OR4F15 | c.750C>G p.F250L | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.861); catalogued as COSV100173839, COSV59968502; called by muse, mutect2, varscan2
- OR4K14 | c.917G>C p.R306P | Missense Mutation (SNP) | VAF 37/217 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV59292340, COSV59292361; called by muse, mutect2, varscan2
- OR4K5 | c.408G>C p.M136I | Missense Mutation (SNP) | VAF 52/651 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.088); catalogued as COSV100262525, COSV60002621; called by muse, mutect2
- OR4M1 | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 20/378 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60059954; called by muse, mutect2
- OR4N2 | c.620C>A p.T207K | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as COSV60050439, COSV60050464; called by muse, mutect2
- OR51B2 | c.794A>C p.N265T | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV60916163; called by muse, mutect2, varscan2
- OR51L1 | c.698G>T p.R233L | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as COSV58624167; called by muse, mutect2, varscan2
- OR5AN1 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 44/231 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58321770; called by muse, mutect2, varscan2
- OR5L1 | c.595C>G p.L199V | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as COSV61733040; called by muse, mutect2, varscan2
- OR5R1 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368362913, COSV56572291; called by muse, mutect2, varscan2
- OR6N1 | c.644T>G p.L215R | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.691); catalogued as COSV58647612; called by muse, mutect2
- OR7E24 | c.739C>A p.P247T | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV71702146, COSV71702359; called by muse, mutect2, varscan2
- OR8D1 | c.364C>A p.R122S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV63441743, COSV63442931; called by muse, mutect2
- OR8J3 | c.680G>T p.R227M | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56879699, COSV56884521; called by muse, mutect2, varscan2
- OR8K5 | c.657G>T p.M219I | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as COSV57888120, COSV57890876; called by muse, mutect2, varscan2
- OVCH1 | c.2582C>A p.P861Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV58960447; called by muse, mutect2
- PARP16 | c.278A>T p.K93M | Missense Mutation (SNP) | VAF 83/300 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV56034807; called by muse, mutect2, varscan2
- PARP8 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated, low confidence (0.66); PolyPhen probably damaging (0.991); catalogued as rs1421501673, COSV55857271; called by muse, mutect2, varscan2
- PCCA | c.1685C>T p.S562L | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT tolerated (0.67); PolyPhen benign (0.04); catalogued as CM991023, COSV66189217, COSV66194414; called by muse, mutect2, varscan2
- PCDH15 | c.4631C>A p.T1544K | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.227); catalogued as COSV64679263; called by muse, mutect2, varscan2
- PCDH15 | c.1889G>T p.R630M | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57273258, COSV57391082; called by muse, mutect2, varscan2
- PCDHB14 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.812); catalogued as COSV99505551; called by muse, mutect2, varscan2
- PCDHGA1 | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.021); catalogued as COSV65295383, COSV65296145; called by muse, mutect2, varscan2
- PCDHGA1 | c.302C>A p.P101Q | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.039); catalogued as COSV100965926, COSV65297686; called by muse, mutect2, varscan2
- PCDHGA2 | c.287G>T p.C96F | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV53912902; called by muse, mutect2, varscan2
- PCDHGA2 | c.1678C>A p.P560T | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53912909; called by muse, mutect2, varscan2
- PCMT1 | c.425A>T p.D142V | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66303076; called by muse, mutect2, varscan2
- PDGFRA | c.2618C>A p.T873N | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57265723; called by muse, mutect2, varscan2
- PFAS | c.2641G>T p.D881Y | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58978977; called by muse, mutect2, varscan2
- PIK3CG | c.844G>C p.V282L | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.64); PolyPhen benign (0.009); catalogued as COSV100783011, COSV63246552; called by muse, mutect2, varscan2
- PJA2 | c.1531A>T p.S511C | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63272074; called by muse, mutect2, varscan2
- PLAAT5 | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV57136366; called by muse, mutect2, varscan2
- PLEKHM3 | c.1870G>C p.E624Q | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV66815852; called by muse, mutect2, varscan2
- PM20D2 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs543295537, COSV51529928; called by muse, mutect2, varscan2
- PODXL | c.846G>C p.Q282H (on ENST00000378555 / NM_001018111.3; = p.Q250H on NM_005397.4) | Missense Mutation (SNP) | VAF 33/235 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.549); catalogued as COSV59868980; called by muse, mutect2, varscan2
- POLR3A | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.124); catalogued as COSV64930482; called by muse, mutect2, varscan2
- POU3F2 | c.946C>A p.L316M | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100098968; called by muse, mutect2, varscan2
- POU3F2 | c.947T>A p.L316Q | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100098973; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.647A>T p.E216V | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV53451346; called by muse, mutect2, varscan2
- PPARD | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1434449026, COSV61099023; called by muse, mutect2, varscan2
- PPM1L | c.610G>T p.D204Y | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as COSV55561758, COSV55565463; called by muse, mutect2, varscan2
- PPP1R21 | c.1850A>T p.Q617L | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.112); catalogued as COSV54282750; called by muse, mutect2, varscan2
- PPP4R3A | c.1042C>G p.Q348E | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.444); catalogued as COSV61503770, COSV61506840; called by muse, mutect2
- PRDM9 | c.1757G>T p.G586V | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57003688; called by muse, mutect2, varscan2
- PRICKLE1 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV61542279; called by muse, mutect2, varscan2
- PRKD1 | c.1991G>T p.G664V | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59561529, COSV59568436; called by muse, mutect2, varscan2
- PRKG1 | c.1829G>T p.C610F | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64767627, COSV64776800; called by muse, mutect2, varscan2
- PRMT5 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV53545118; called by muse, mutect2, varscan2
- PROM2 | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.059); catalogued as COSV58297150; called by muse, mutect2, varscan2
- PRSS1 | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs141011596; called by muse, varscan2
- PRUNE2 | c.4307G>T p.S1436I | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.057); catalogued as COSV65038805; called by muse, mutect2, varscan2
- PTBP2 | c.125G>T p.S42I (on ENST00000426398 / NM_001300986.2; = p.S34I on NM_021190.4) | Missense Mutation (SNP) | VAF 108/259 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.158); catalogued as COSV64623629; called by muse, mutect2, varscan2
- PTPRZ1 | c.1568_1569del p.V523Dfs*2 | Frame Shift Del (DEL) | VAF 20/126 reads (16%) | catalogued as rs1425489055; called by pindel, varscan2
- PXDNL | c.340G>T p.D114Y | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV62481764; called by muse, mutect2, varscan2
- RAB37 | c.187G>T p.V63F | Missense Mutation (SNP) | VAF 69/209 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61193080; called by muse, mutect2, varscan2
- RAB41 | c.236T>G p.I79R (on ENST00000374473 / NM_001363807.1; = p.I78R on NM_001032726.3) | Missense Mutation (SNP) | VAF 48/82 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV52103420; called by muse, varscan2
- RARS2 | c.1690G>T p.A564S | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.34); catalogued as COSV65760362; called by muse, mutect2, varscan2
- RBM19 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs140564219; called by muse, mutect2, varscan2
- RCN2 | c.701G>C p.R234T | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs934551088, COSV58031153; called by muse, mutect2, varscan2
- ROBO2 | c.1350C>G p.S450R | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.89); PolyPhen benign (0.101); catalogued as COSV59901287; called by muse, mutect2, varscan2
- RPE65 | c.614A>G p.N205S | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as rs61752887, CM057733, COSV52013951; ClinVar: not provided; called by muse, mutect2, varscan2
- RPS19 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV55743161; called by muse, mutect2, varscan2
- RRBP1 | c.2881G>C p.E961Q (on ENST00000377813 / NM_001365613.2; = p.E528Q on NM_004587.3) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as COSV55697021; called by muse, mutect2, varscan2
- RTRAF | c.101A>G p.D34G | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55562416; called by muse, mutect2, varscan2
- RUFY2 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV61190657; called by muse, mutect2, varscan2
- RUNDC1 | c.822C>G p.I274M | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64511548; called by muse, mutect2, varscan2
- RYR2 | c.6268C>T p.R2090W | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1284802339, COSV63669937; called by muse, mutect2, varscan2
- RYR2 | c.10514T>A p.V3505E | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63669948; called by muse, mutect2, varscan2
- RYR2 | c.12691C>A p.P4231T | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1271445965, COSV63669962; called by muse, mutect2, varscan2
- RYR3 | c.6889C>A p.R2297S (on ENST00000389232; = p.R2298S on NM_001036.6) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63109571; called by mutect2, varscan2
- SAMD8 | c.587G>C p.R196T | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.601); catalogued as COSV65509257; called by muse, mutect2, varscan2
- SCARB1 | c.457A>G p.M153V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV55544736; called by muse, mutect2, varscan2
- SCG2 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 117/200 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756798030, COSV59539295; called by muse, mutect2, varscan2
- SCN11A | c.2525C>T p.A842V | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV100182892, COSV56567158; called by muse, mutect2, varscan2
- SEC24C | c.3170A>G p.K1057R | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV59540503; called by muse, mutect2, varscan2
- SEMA4D | c.2152C>T p.P718S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs921346331, COSV59391937; called by muse, mutect2, varscan2
- SERINC5 | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.132); catalogued as COSV72595709; called by muse, mutect2
- SERPINA4 | c.899G>T p.R300M | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54069144; called by muse, mutect2, varscan2
- SGCZ | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV66001834, COSV66030907; called by muse, mutect2, varscan2
- SH2D4B | c.368T>C p.I123T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV57893563; called by muse, mutect2, varscan2
- SKAP1 | c.205G>C p.D69H | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV61144839; called by muse, mutect2, varscan2
- SLAMF6 | c.368C>A p.T123N | Missense Mutation (SNP) | VAF 36/270 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.024); catalogued as COSV63586582; called by muse, mutect2, varscan2
- SLC27A6 | c.737C>A p.A246D | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.285); catalogued as COSV99322169; called by muse, mutect2, varscan2
- SLC35F1 | c.386G>T p.W129L | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64500019, COSV64506621; called by muse, mutect2, varscan2
- SLC4A3 | c.2417C>A p.A806D | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as COSV56092166; called by muse, mutect2, varscan2
- SLC4A5 | c.1429G>C p.E477Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.653); catalogued as COSV61025474; called by muse, mutect2, varscan2
- SLC5A4 | c.419G>C p.R140P | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV56669102, COSV56673583; called by muse, mutect2, varscan2
- SLCO1B1 | c.457G>C p.A153P | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV104376739, COSV57008262; called by muse, mutect2, varscan2
- SLIT2 | c.3916G>T p.G1306C | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56564131; called by muse, mutect2, varscan2
- SLITRK1 | c.1042G>T p.D348Y | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV65674618; called by muse, mutect2, varscan2
- SMAD9 | c.535G>T p.D179Y | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as COSV63204263; called by muse, mutect2, varscan2
- SMC3 | c.3134A>T p.Q1045L | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV62419330; called by muse, mutect2, varscan2
- SMYD1 | c.541G>C p.G181R | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs143639398, COSV70224612, COSV70225024; called by muse, mutect2, varscan2
- SORCS1 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as rs1238754962, COSV53848358, COSV53865482; called by muse, mutect2, varscan2
- SORL1 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV52750850; called by mutect2, varscan2
- SOX13 | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV65826429; called by muse, mutect2
- SPAG16 | c.943G>T p.D315Y | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV59077400; called by muse, mutect2, varscan2
- SPAG16 | c.1737G>T p.Q579H | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100435117, COSV56966988; called by muse, mutect2, varscan2
- SPATA5 | c.2318A>T p.N773I | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56773159; called by muse, mutect2, varscan2
- SPEN | c.2504C>G p.S835C | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV65358951, COSV65363069; called by muse, mutect2, varscan2
- SPIN3 | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66529041, COSV66529484, COSV99059184; called by muse, mutect2, varscan2
- SPNS3 | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as COSV61069360, COSV61070363; called by muse, mutect2, varscan2
- SPON2 | c.167T>C p.F56S | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52054449; called by muse, mutect2, varscan2
- SPTA1 | c.2898G>T p.Q966H | Missense Mutation (SNP) | VAF 62/236 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV63750156; called by muse, mutect2
- SPTSSA | c.180C>G p.I60M | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV53294494; called by muse, mutect2, varscan2
- SRGAP3 | c.320G>T p.R107L | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64531272; called by muse, mutect2, varscan2
- SSH1 | c.412A>G p.T138A | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV58454976; called by muse, mutect2, varscan2
- SSR3 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as COSV54020147; called by muse, mutect2
- STAT1 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.023); catalogued as COSV63115287; called by muse, mutect2, varscan2
- STK32B | c.593G>C p.R198T | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs776507984, COSV51476436; called by muse, mutect2, varscan2
- STOML3 | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65510166; called by muse, mutect2, varscan2
- SVEP1 | c.7319G>A p.C2440Y | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52836738; called by muse, mutect2, varscan2
- SYNE2 | c.1390G>C p.E464Q | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV59942453, COSV59970046; called by muse, mutect2, varscan2
- SYNE2 | c.16406C>A p.P5469Q | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.145); catalogued as COSV59942461; called by muse, mutect2, varscan2
- SYNE3 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs376779070, COSV62077729; called by muse, mutect2, varscan2
- SYNGAP1 | c.2239G>A p.V747I | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV53378998; called by muse, mutect2, varscan2
- SYNPR | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0.031); catalogued as COSV55723604, COSV55729775; called by muse, mutect2, varscan2
- TAF8 | c.658A>C p.T220P | Missense Mutation (SNP) | VAF 172/495 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV65895777; called by muse, varscan2
- TAS2R19 | c.278A>G p.H93R | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV66828077; called by muse, mutect2, varscan2
- TBX22 | c.1203G>T p.Q401H | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV64785246; called by muse, mutect2, varscan2
- TBXAS1 | c.842T>C p.M281T | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV54942109; called by muse, mutect2, varscan2
- TEX14 | c.1022G>T p.R341L (on ENST00000240361 / NM_001201457.2; = p.R335L on NM_031272.5) | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV53613140; called by muse, mutect2, varscan2
- TEX14 | c.251+1G>T p.X84_splice | Splice Site (SNP) | VAF 13/47 reads (28%) | catalogued as COSV53613159; called by muse, mutect2
- TEX26 | c.703A>G p.T235A | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as COSV66839573; called by muse, mutect2, varscan2
- THNSL2 | c.571+1G>T p.X191_splice | Splice Site (SNP) | VAF 11/55 reads (20%) | catalogued as rs1302616509, COSV59082206; called by muse, mutect2, varscan2
- THSD7A | c.2983G>C p.G995R | Missense Mutation (SNP) | VAF 76/381 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70260547, COSV70261638; called by muse, mutect2, varscan2
- TJP2 | c.377C>A p.A126E | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as rs1204229288; called by muse, mutect2
- TM9SF2 | c.828G>T p.E276D | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.098); catalogued as COSV64506358; called by muse, mutect2, varscan2
- TMEM176A | c.418T>A p.F140I | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as COSV50240367; called by muse, mutect2, varscan2
- TMEM33 | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as COSV52561548; called by muse, mutect2, varscan2
- TMEM74 | c.263C>G p.S88* | Nonsense Mutation (SNP) | VAF 43/142 reads (30%) | catalogued as COSV52462702; called by muse, mutect2, varscan2
- TMEM81 | c.40G>T p.G14W | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.306); catalogued as COSV52703229; called by muse, mutect2, varscan2
- TMPRSS15 | c.1256A>T p.E419V | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as COSV53036165; called by muse, mutect2, varscan2
- TNIK | c.1683C>A p.D561E | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.145); catalogued as COSV52676363; called by muse, mutect2
- TP53 | c.472del p.R158Afs*12 | Frame Shift Del (DEL) | VAF 18/47 reads (38%) | catalogued as CM004341, CM121763, COSV52677865, COSV52699654, COSV52778687; called by mutect2, pindel, varscan2
- TPD52 | c.576del p.K192Nfs*11 (on ENST00000379097 / NM_001025252.3; = p.K152Nfs*11 on NM_005079.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 19/82 reads (23%) | catalogued as COSV66951086; called by mutect2, pindel*, varscan2
- TPTE | c.517G>A p.D173N (on ENST00000618007 / NM_199261.4; = p.D155N on NM_199259.4) | Missense Mutation (SNP) | VAF 15/165 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.115); catalogued as rs748367707; called by muse, mutect2, varscan2
- TPX2 | c.1969C>T p.Q657* | Nonsense Mutation (SNP) | VAF 25/159 reads (16%) | catalogued as COSV55918012; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1183C>A p.L395I | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.509); catalogued as COSV50550916; called by muse, mutect2, varscan2
- TRIM25 | c.944G>T p.R315L | Missense Mutation (SNP) | VAF 196/486 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs144571863, COSV57543532; called by muse, mutect2, varscan2
- TRIOBP | c.1327C>T p.P443S | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); catalogued as COSV60374957; called by muse, varscan2
- TRIOBP | c.3823G>T p.D1275Y | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV60374964; called by muse, mutect2, varscan2
- TRPA1 | c.174A>T p.R58S | Missense Mutation (SNP) | VAF 46/80 reads (58%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs375975650; called by muse, mutect2, varscan2
- TRPC6 | c.2259C>A p.Y753* | Nonsense Mutation (SNP) | VAF 22/92 reads (24%) | catalogued as COSV60251776; called by muse, mutect2, varscan2
- TRPM3 | c.964C>A p.Q322K (on ENST00000357533 / NM_001366142.2; = p.Q167K on NM_020952.6) | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV62468036; called by muse, mutect2, varscan2
- TSSK6 | c.706C>G p.L236V | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.091); catalogued as rs1218726158, COSV53062835; called by muse, mutect2
- TTC27 | c.2208C>A p.C736* | Nonsense Mutation (SNP) | VAF 28/158 reads (18%) | catalogued as COSV58649577; called by muse, mutect2, varscan2
- TTN | c.31648C>A p.P10550T (on ENST00000591111; = p.P9623T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/54 reads (46%) | PolyPhen benign (0.015); catalogued as COSV59932487; called by muse, mutect2, varscan2
- TTN | c.27694T>A p.L9232I (on ENST00000591111; = p.L8305I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/81 reads (42%) | PolyPhen benign (0.003); catalogued as COSV59932494; called by muse, mutect2, varscan2
- TTN | c.27379C>A p.Q9127K (on ENST00000591111; = p.Q8200K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/83 reads (18%) | PolyPhen benign (0.003); catalogued as COSV59932502; called by muse, mutect2, varscan2
- TTN | c.23300C>T p.P7767L (on ENST00000591111; = p.P6840L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | PolyPhen benign (0.178); catalogued as COSV59932516; called by muse, mutect2, varscan2
- TTN | c.7765T>A p.L2589M (on ENST00000591111; = p.L2543M on NM_003319.4) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | PolyPhen probably damaging (0.999); catalogued as COSV59932526; called by muse, mutect2, varscan2
- TYR | c.1354C>A p.L452I | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as CM091282, COSV54471811; called by muse, mutect2, varscan2
- UBAP2L | c.1563G>C p.L521F | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55169281; called by muse, mutect2, varscan2
- ULK4 | c.2437G>T p.E813* | Nonsense Mutation (SNP) | VAF 34/85 reads (40%) | catalogued as COSV57201853, COSV57213458; called by muse, mutect2, varscan2
- USF3 | c.3563A>T p.Q1188L | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.272); catalogued as COSV57070675; called by muse, mutect2, varscan2
- USH2A | c.14293G>A p.V4765I | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as rs530395989, COSV56339098; called by muse, mutect2
- USH2A | c.5776+1G>T p.X1926_splice | Splice Site (SNP) | VAF 6/73 reads (8%) | catalogued as CS080750, COSV100229168; called by muse, mutect2
- USP2 | c.63C>G p.H21Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV52731585; called by muse, mutect2, varscan2
- USP25 | c.1150G>T p.G384* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as rs1315719889, COSV53482028; called by muse, mutect2, varscan2
- USP31 | c.1400G>T p.G467V | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54850228; called by muse, mutect2, varscan2
- UST | c.1166T>A p.I389N | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.083); catalogued as COSV66546106; called by muse, mutect2, varscan2
- VEPH1 | c.1937G>T p.W646L | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV62876785; called by muse, mutect2, varscan2
- VPS37A | c.881G>C p.R294T | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV61364359; called by muse, mutect2, varscan2
- VPS51 | c.1924G>T p.D642Y | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54206417; called by muse, mutect2, varscan2
- WAPL | c.945G>T p.M315I | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV53933084; called by muse, mutect2, varscan2
- WDR77 | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1171177910, COSV52384787; called by muse, mutect2, varscan2
- XIRP2 | c.86G>T p.R29M | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.267); catalogued as COSV99738636; called by muse, mutect2, varscan2
- XIRP2 | c.87G>T p.R29S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.015); catalogued as COSV99738643; called by muse, mutect2, varscan2
- YWHAB | c.173G>T p.R58L | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); catalogued as COSV62304010; called by muse, mutect2, varscan2
- ZBTB4 | c.2120G>A p.W707* | Nonsense Mutation (SNP) | VAF 12/84 reads (14%) | catalogued as COSV60977627; called by muse, mutect2, varscan2
- ZCWPW2 | c.203A>G p.Y68C | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs942092881, COSV67497939; called by muse, mutect2, varscan2
- ZDHHC1 | c.458G>T p.C153F | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62214713; called by muse, mutect2, varscan2
- ZEB2 | c.3492G>T p.E1164D | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.956); catalogued as COSV57952950; called by muse, mutect2, varscan2
- ZFHX4 | c.6751C>A p.P2251T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51455010, COSV51491910; called by muse, mutect2
- ZNF100 | c.1151G>T p.R384L | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.009); catalogued as COSV59746791; called by muse, mutect2, varscan2
- ZNF134 | c.1257G>C p.Q419H | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.601); catalogued as COSV68696184; called by muse, mutect2, varscan2
- ZNF223 | c.557G>A p.C186Y | Missense Mutation (SNP) | VAF 87/197 reads (44%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as rs746319751, COSV71571805; called by muse, mutect2, varscan2
- ZNF226 | c.1196G>C p.S399T | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.268); catalogued as COSV56196177; called by muse, mutect2, varscan2
- ZNF248 | c.1241G>T p.G414V | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1344929011, COSV61997312; called by muse, mutect2, varscan2
- ZNF292 | c.1048A>G p.I350V | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.376); catalogued as rs1486267251, COSV60536598; called by muse, mutect2, varscan2
- ZNF333 | c.369G>C p.L123F | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); catalogued as COSV52885165; called by muse, varscan2
- ZNF337 | c.1082C>A p.S361* | Nonsense Mutation (SNP) | VAF 12/81 reads (15%) | catalogued as COSV53320548; called by mutect2, varscan2
- ZNF556 | c.430G>T p.V144L | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV56911250; called by muse, mutect2, varscan2
- ZNF598 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs374490857; called by muse, mutect2
- ZNF675 | c.1600A>T p.K534* | Nonsense Mutation (SNP) | VAF 11/72 reads (15%) | catalogued as COSV63095293; called by muse, mutect2, varscan2
- ZNF99 | c.1766G>C p.G589A | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV68055074; called by muse, mutect2, varscan2
- ADA2 | c.21_22dup p.E8Vfs*24 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by mutect2, pindel
- BCO1 | c.1085_1086delinsT p.P362Lfs*14 | Frame Shift Del (DEL) | VAF 22/76 reads (29%) | called by pindel, varscan2*
- COL6A3 | c.5011G>C p.E1671Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.398); called by muse, mutect2
- FAT2 | c.8791del p.L2931Wfs*101 | Frame Shift Del (DEL) | VAF 34/186 reads (18%) | called by mutect2, pindel, varscan2
- FREM1 | c.903_904delinsT p.V302Cfs*11 | Frame Shift Del (DEL) | VAF 31/120 reads (26%) | called by pindel, varscan2*
- FRG2 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- FRYL | c.96dup p.E33* | Frame Shift Ins (INS) | VAF 28/108 reads (26%) | called by mutect2, pindel, varscan2
- KIAA0232 | c.2663del p.G888Dfs*33 | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | called by mutect2, pindel, varscan2
- LRFN2 | c.1665_1676del p.R556_V559del | In Frame Del (DEL) | VAF 6/57 reads (11%) | called by mutect2, pindel
- NF1 | c.4391del p.F1464Sfs*5 (on ENST00000358273 / NM_001042492.3; = p.F1443Sfs*5 on NM_000267.3) | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | called by mutect2, varscan2
- OR13A1 | c.285_286del p.M96Afs*43 | Frame Shift Del (DEL) | VAF 4/23 reads (17%) | called by mutect2, pindel, varscan2
- PCDHGA3 | c.2195dup p.L732Ffs*55 | Frame Shift Ins (INS) | VAF 16/66 reads (24%) | called by mutect2, pindel, varscan2
- PRAMEF14 | c.390T>A p.S130R | Missense Mutation (SNP) | VAF 58/335 reads (17%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PRAMEF14 | c.98G>T p.R33M | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- SEC24C | c.2099del p.P700Lfs*37 | Frame Shift Del (DEL) | VAF 9/81 reads (11%) | called by mutect2, pindel, varscan2
- SPANXN3 | c.174del p.K59Rfs*5 | Frame Shift Del (DEL) | VAF 60/100 reads (60%) | called by mutect2, pindel*, varscan2
- SPATA31A1 | c.1072A>T p.K358* | Nonsense Mutation (SNP) | VAF 61/243 reads (25%) | called by muse, mutect2, varscan2
- TCEAL6 | c.525dup p.G176Rfs*26 | Frame Shift Ins (INS) | VAF 22/68 reads (32%) | called by mutect2, pindel, varscan2
- USP6 | c.3679del p.A1227Pfs*17 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | called by mutect2, pindel, varscan2
- ZNF449 | c.1217_1232del p.T406Sfs*16 | Frame Shift Del (DEL) | VAF 28/115 reads (24%) | called by mutect2, pindel, varscan2
- A2ML1 | c.1569C>T p.T523= | Silent (SNP) | VAF 29/111 reads (26%) | catalogued as rs1455152222, COSV55287163; called by muse, mutect2, varscan2
- ABCB5 | c.159G>T p.L53= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV68855527; called by muse, mutect2, varscan2
- ABCB5 | c.1599C>A p.I533= (on ENST00000404938 / NM_001163941.2; = p.I88= on NM_178559.6) | Silent (SNP) | VAF 62/112 reads (55%) | catalogued as COSV51705118; called by muse, mutect2, varscan2
- ABCB8 | c.1614G>T p.L538= (on ENST00000297504 / NM_001282291.2; = p.L521= on NM_007188.5) | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV99873804; called by muse, mutect2, varscan2
- ABHD3 | c.810T>C p.Y270= | Silent (SNP) | VAF 66/126 reads (52%) | catalogued as COSV56675885; called by muse, mutect2, varscan2
- ABL2 | c.2052A>G p.E684= (on ENST00000502732 / NM_007314.4; = p.E669= on NM_005158.5) | Silent (SNP) | VAF 44/438 reads (10%) | catalogued as COSV61011691; called by muse, mutect2, varscan2
- ACTN1 | c.1857G>T p.T619= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV51989249, COSV51992960, COSV51993749; called by muse, mutect2, varscan2
- ACTN2 | c.711C>A p.T237= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV63977819; called by muse, mutect2
- ADAM19 | c.1932G>A p.R644= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV57424436; called by muse, mutect2, varscan2
- ADAM30 | c.951T>C p.Y317= | Silent (SNP) | VAF 18/118 reads (15%) | catalogued as rs759439950, COSV65560577; called by muse, mutect2, varscan2
- ADRA1B | c.270C>T p.A90= | Silent (SNP) | VAF 28/98 reads (29%) | catalogued as COSV60700810; called by muse, mutect2, varscan2
- AHNAK2 | c.11016G>C p.V3672= | Silent (SNP) | VAF 64/236 reads (27%) | catalogued as COSV60909981; called by muse, mutect2
- ANAPC5 | c.1980A>G p.K660= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV55841796; called by muse, mutect2, varscan2
- ANK2 | c.11856A>C p.S3952= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as rs772699874, COSV99999810; called by muse, mutect2, varscan2
- ANKRD1 | c.387G>T p.L129= | Silent (SNP) | VAF 21/118 reads (18%) | catalogued as COSV63310932; called by muse, mutect2, varscan2
- ANKRD22 | c.222A>G p.R74= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as COSV64237457; called by muse, varscan2
- ANO7 | c.2547C>T p.I849= (on ENST00000274979; = p.I795= on NM_001370694.2) | Silent (SNP) | VAF 41/180 reads (23%) | catalogued as COSV51469471; called by muse, mutect2, varscan2
- APBB1IP | c.51A>T p.G17= | Silent (SNP) | VAF 43/172 reads (25%) | catalogued as COSV63301783; called by muse, mutect2, varscan2
- AQR | c.3234A>T p.L1078= | Silent (SNP) | VAF 22/111 reads (20%) | catalogued as COSV50030314; called by muse, mutect2, varscan2
- ARID3C | c.249C>A p.P83= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV66697671; called by muse, mutect2, varscan2
- ATP2B2 | c.558C>A p.I186= | Silent (SNP) | VAF 53/240 reads (22%) | catalogued as rs139130148, COSV59491520; called by muse, mutect2, varscan2
- BCAS3 | c.2388C>T p.R796= (on ENST00000390652 / NM_001353144.2; = p.R781= on NM_017679.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV66770958; called by muse, mutect2, varscan2
- CACNA1A | c.723A>T p.A241= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV64192247; called by muse, mutect2, varscan2
- CCDC88A | c.1707C>T p.S569= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV55058081; called by muse, mutect2, varscan2
- CCNB1IP1 | c.348C>T p.G116= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as rs923496966, COSV62302509; called by muse, mutect2, varscan2
- CCT7 | c.882C>T p.P294= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as rs774738780, COSV57821527; called by muse, mutect2, varscan2
- CDH23 | c.5565C>A p.P1855= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV56452104; called by muse, mutect2, varscan2
- CDH26 | c.1242G>T p.L414= | Silent (SNP) | VAF 59/432 reads (14%) | catalogued as COSV54843892; called by muse, mutect2, varscan2
- CELSR3 | c.3273A>C p.A1091= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV50841821; called by muse, mutect2, varscan2
- CENPJ | c.3543G>A p.V1181= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as COSV55035872; called by muse, mutect2, varscan2
- CHRM1 | c.63T>A p.G21= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV61006264; called by muse, mutect2, varscan2
- CLPB | c.249C>T p.L83= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs200845330, COSV53628020, COSV53632212, COSV99577898; ClinVar: likely benign; called by muse, mutect2, varscan2
- CNTNAP5 | c.618C>A p.S206= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as rs367708864; called by muse, mutect2, varscan2
- COL19A1 | c.3099G>A p.R1033= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV59567891; called by muse, mutect2, varscan2
- CSMD1 | c.9666G>T p.T3222= (on ENST00000520002; = p.T3221= on NM_033225.6) | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs749126806, COSV59294241; called by muse, varscan2
- CSMD1 | c.2706G>T p.P902= (on ENST00000520002; = p.P901= on NM_033225.6) | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV59294283; called by muse, mutect2, varscan2
- DCAF12L1 | c.6C>G p.A2= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV64421305; called by muse, mutect2, varscan2
- DNAH3 | c.2457G>A p.K819= | Silent (SNP) | VAF 65/143 reads (45%) | catalogued as rs1384592894, COSV54509080, COSV99771271; called by muse, mutect2, varscan2
- DPYD | c.942C>G p.A314= | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as COSV64592827; called by muse, mutect2, varscan2
- DRD1 | c.420C>A p.A140= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV67104313; called by muse, mutect2, varscan2
- EPHX4 | c.696A>T p.I232= | Silent (SNP) | VAF 14/109 reads (13%) | catalogued as COSV64889121; called by muse, mutect2
- EYA4 | c.1536C>A p.A512= (on ENST00000531901 / NM_001301013.1; = p.A506= on NM_004100.5) | Silent (SNP) | VAF 52/98 reads (53%) | catalogued as COSV62047489; called by muse, mutect2, varscan2
- FAIM2 | c.216C>T p.S72= | Silent (SNP) | VAF 5/67 reads (7%) | catalogued as COSV57738156; called by muse, mutect2
- FBXO16 | c.549A>G p.L183= | Silent (SNP) | VAF 93/137 reads (68%) | catalogued as COSV60774791; called by muse, mutect2, varscan2
- FOXC2 | c.363C>A p.R121= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as COSV100234103; called by muse, mutect2, varscan2
- FRG2C | c.660C>A p.A220= | Silent (SNP) | VAF 15/83 reads (18%) | called by muse, mutect2, varscan2
- FRS2 | c.1239G>T p.R413= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV100165810, COSV54723901; called by muse, mutect2, varscan2
- GAS2L3 | c.1464C>T p.H488= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs758286468, COSV57156407; called by muse, mutect2, varscan2
- GBP4 | c.1296G>A p.L432= | Silent (SNP) | VAF 81/384 reads (21%) | catalogued as COSV63253347; called by muse, mutect2, varscan2
- GPR135 | c.1449A>G p.K483= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV67749492; called by muse, mutect2, varscan2
- GPR21 | c.588G>A p.V196= | Silent (SNP) | VAF 28/123 reads (23%) | catalogued as COSV65378859; called by muse, mutect2, varscan2
- GPSM1 | c.78G>A p.A26= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs372738428; called by muse, mutect2, varscan2
- GRM5 | c.1836C>T p.S612= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV100555112, COSV59595342; called by muse, mutect2, varscan2
- HARS2 | c.999A>G p.T333= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV51226853; called by muse, mutect2, varscan2
- HDAC5 | c.1038C>T p.L346= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV56817632; called by muse, mutect2, varscan2
- HDAC9 | c.1635G>C p.V545= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV67769173, COSV67775693; called by muse, mutect2, varscan2
- ICE1 | c.3429G>A p.V1143= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV56820826; called by muse, mutect2, varscan2
- IFI44L | c.921C>T p.I307= | Silent (SNP) | VAF 31/197 reads (16%) | catalogued as COSV60726945; called by muse, mutect2, varscan2
- IFT172 | c.300T>A p.G100= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as COSV53131044, COSV53140361; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.33G>T p.V11= | Silent (SNP) | VAF 40/479 reads (8%) | called by muse, mutect2
- INSR | c.4146C>T p.S1382= | Silent (SNP) | VAF 20/131 reads (15%) | catalogued as COSV57159153; called by muse, mutect2, varscan2
- INTS1 | c.6012G>A p.G2004= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV67176653; called by muse, mutect2, varscan2
- ITSN2 | c.2145A>G p.K715= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as COSV61944576; called by muse, mutect2, varscan2
- KALRN | c.2992C>A p.R998= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV53755893; called by muse, mutect2, varscan2
- KCNK6 | c.585C>A p.L195= | Silent (SNP) | VAF 100/292 reads (34%) | catalogued as COSV54579103, COSV54581122; called by muse, mutect2, varscan2
- KCNN3 | c.576C>T p.S192= | Silent (SNP) | VAF 15/111 reads (14%) | catalogued as rs1432832525, COSV55213574; called by muse, mutect2, varscan2
- KIF21B | c.1647G>A p.E549= | Silent (SNP) | VAF 27/231 reads (12%) | catalogued as rs1414689344, COSV59754027; called by muse, mutect2, varscan2
- KIRREL1 | c.846G>A p.T282= | Silent (SNP) | VAF 36/252 reads (14%) | catalogued as COSV63285802; called by muse, mutect2, varscan2
- KLHL4 | c.1258C>A p.R420= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV64139892; called by muse, mutect2, varscan2
- KMT5B | c.2337C>T p.I779= | Silent (SNP) | VAF 58/287 reads (20%) | catalogued as COSV58564400; called by muse, mutect2, varscan2
- KRTAP9-4 | c.237C>A p.P79= | Silent (SNP) | VAF 35/123 reads (28%) | catalogued as COSV61897656; called by muse, mutect2, varscan2
- KSR2 | c.1764G>C p.A588= | Silent (SNP) | VAF 65/148 reads (44%) | catalogued as COSV56668089; called by muse, mutect2, varscan2
- LGALS9 | c.882G>A p.L294= (on ENST00000395473 / NM_009587.3; = p.L262= on NM_002308.4) | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV56348210; called by muse, mutect2
- LGR6 | c.537C>A p.V179= (on ENST00000367278 / NM_001017403.1; = p.V127= on NM_021636.3) | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV55152852, COSV99707836; called by muse, mutect2, varscan2
- LRFN5 | c.1692C>A p.T564= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as COSV53246927; called by muse, mutect2, varscan2
- LRP1 | c.11538C>T p.L3846= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV54504603, COSV99675504; called by muse, mutect2, varscan2
- LRRN3 | c.594T>C p.N198= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as COSV100067966; called by muse, mutect2, varscan2
- LTBP1 | c.4422C>T p.P1474= (on ENST00000404816 / NM_206943.4; = p.P1148= on NM_000627.4) | Silent (SNP) | VAF 53/149 reads (36%) | catalogued as COSV55376688, COSV55378832; called by muse, mutect2, varscan2
- MAP3K21 | c.2190G>T p.L730= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as COSV64041241; called by muse, mutect2, varscan2
- MARCHF10 | c.960G>C p.G320= | Silent (SNP) | VAF 105/373 reads (28%) | catalogued as COSV60885759; called by muse, mutect2, varscan2
- MARK2 | c.2280C>T p.L760= (on ENST00000402010 / NM_001039469.2; = p.L696= on NM_004954.5) | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as COSV56849594; called by muse, mutect2, varscan2
- MAST4 | c.7209G>A p.A2403= (on ENST00000403625 / NM_001164664.2; = p.A2214= on NM_015183.3) | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV55118427; called by muse, mutect2, varscan2
- MEP1A | c.312C>T p.L104= | Silent (SNP) | VAF 32/170 reads (19%) | catalogued as rs540101823, COSV57918524; called by muse, mutect2, varscan2
- MUC16 | c.27741A>C p.T9247= | Silent (SNP) | VAF 9/126 reads (7%) | catalogued as COSV67452246; called by muse, mutect2
- MYH14 | c.3810G>A p.R1270= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV51812214; called by muse, mutect2, varscan2
- MYH6 | c.5658G>A p.E1886= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV59305091; called by muse, mutect2, varscan2
- MYH8 | c.3993C>A p.A1331= | Silent (SNP) | VAF 37/73 reads (51%) | catalogued as COSV67961300; called by muse, mutect2, varscan2
- MYO10 | c.3591C>T p.C1197= | Silent (SNP) | VAF 24/224 reads (11%) | catalogued as rs754365346, COSV57018152; called by muse, mutect2, varscan2
- NAPEPLD | c.618G>A p.E206= | Silent (SNP) | VAF 57/140 reads (41%) | catalogued as COSV58521494; called by muse, mutect2, varscan2
- NCDN | c.477G>A p.L159= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as COSV57843107; called by muse, mutect2, varscan2
- NEO1 | c.777C>A p.V259= | Silent (SNP) | VAF 47/124 reads (38%) | catalogued as COSV56068665, COSV56074070; called by muse, mutect2, varscan2
- NEU3 | c.1152C>T p.P384= | Silent (SNP) | VAF 39/91 reads (43%) | catalogued as COSV53635900; called by muse, mutect2, varscan2
- NPR3 | c.819G>T p.V273= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as COSV54085307; called by muse, mutect2, varscan2
- NR2F6 | c.897G>A p.S299= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV52242984; called by muse, mutect2
- NRG1 | c.1581G>T p.T527= (on ENST00000405005 / NM_013964.5; = p.T532= on NM_013956.5) | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV55173730, COSV55177457; called by muse, mutect2, varscan2
- NTRK2 | c.810T>C p.N270= | Silent (SNP) | VAF 40/183 reads (22%) | catalogued as COSV52857079; called by muse, mutect2, varscan2
- NXNL2 | c.174G>A p.E58= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV65474252; called by muse, mutect2, varscan2
- ODR4 | c.1011A>G p.K337= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as rs752309117, COSV55216021; called by muse, mutect2, varscan2
- OR11G2 | c.870C>T p.Y290= | Silent (SNP) | VAF 33/152 reads (22%) | catalogued as rs376290528, COSV100639985, COSV62131923; called by muse, mutect2, varscan2
- OR13F1 | c.318C>T p.A106= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV100594683; called by muse, mutect2, varscan2
- OR2C3 | c.693A>T p.S231= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as COSV63574601; called by muse, mutect2, varscan2
- OR51B2 | c.522T>A p.R174= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV60915823, COSV60917071; called by muse, mutect2, varscan2
- OSMR | c.2139C>T p.F713= | Silent (SNP) | VAF 55/240 reads (23%) | catalogued as COSV57082082, COSV99952607; called by muse, mutect2, varscan2
- OTOP2 | c.231C>A p.I77= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV58880991; called by muse, mutect2
- P2RY8 | c.867C>T p.D289= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV67176838; called by muse, mutect2, varscan2
- PACS1 | c.1587C>T p.S529= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as rs370986656, COSV57696821, COSV57697768; called by muse, mutect2, varscan2
- PCDHA3 | c.1854G>A p.A618= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs1554122551, COSV63538759; called by muse, mutect2, varscan2
- PCDHB13 | c.36G>A p.R12= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV99506738; called by muse, mutect2, varscan2
- PDE2A | c.1167C>G p.L389= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV57803710; called by muse, mutect2, varscan2
- PEX11A | c.696A>T p.A232= | Silent (SNP) | VAF 158/319 reads (50%) | catalogued as COSV55583019; called by muse, mutect2, varscan2
- PGBD2 | c.426G>T p.V142= | Silent (SNP) | VAF 75/185 reads (41%) | catalogued as rs374536227, COSV61399769; called by muse, mutect2, varscan2
- PIP | c.339C>G p.V113= | Silent (SNP) | VAF 111/230 reads (48%) | catalogued as COSV52120106; called by muse, mutect2, varscan2
- PLAT | c.1458C>G p.V486= | Silent (SNP) | VAF 31/123 reads (25%) | catalogued as COSV54274587; called by muse, mutect2, varscan2
- PLCB4 | c.1143A>C p.T381= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as COSV53795885; called by muse, mutect2, varscan2
- PLCE1 | c.5436G>T p.V1812= | Silent (SNP) | VAF 22/135 reads (16%) | catalogued as COSV53341357; called by muse, mutect2, varscan2
- PLPPR3 | c.807C>T p.I269= (on ENST00000520876 / NM_001270366.2; = p.I297= on NM_024888.2) | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs781702457, COSV62459053; called by muse, mutect2, varscan2
- POM121L12 | c.162C>A p.P54= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV101374881, COSV68692443; called by muse, mutect2, varscan2
- PPP1R17 | c.207G>T p.P69= | Silent (SNP) | VAF 23/206 reads (11%) | catalogued as COSV59610798; called by muse, mutect2, varscan2
- PPP1R18 | c.1770G>T p.L590= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV51294824; called by muse, mutect2, varscan2
- PRAP1 | c.237T>C p.G79= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV53369309; called by muse, mutect2, varscan2
- PRPF40B | c.636C>T p.P212= (on ENST00000380281; = p.P206= on NM_012272.3) | Silent (SNP) | VAF 22/114 reads (19%) | catalogued as rs1288464202, COSV56058160; called by muse, mutect2, varscan2
- PRSS37 | c.150G>T p.V50= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV63339158; called by muse, mutect2, varscan2
- PRSS58 | c.18C>T p.L6= | Silent (SNP) | VAF 16/128 reads (13%) | catalogued as COSV73488482; called by muse, mutect2, varscan2
- PSMG2 | c.324C>G p.S108= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as rs760762445, COSV58287835; called by muse, mutect2, varscan2
- PTCHD4 | c.219G>A p.L73= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV59779792; called by muse, mutect2, varscan2
- PTPRA | c.867G>T p.G289= | Silent (SNP) | VAF 48/184 reads (26%) | catalogued as COSV53779242, COSV53789620; called by mutect2, varscan2
- RHBDD1 | c.297G>T p.L99= | Silent (SNP) | VAF 87/184 reads (47%) | catalogued as COSV58125173; called by muse, mutect2, varscan2
- RNF133 | c.720A>T p.R240= | Silent (SNP) | VAF 59/264 reads (22%) | catalogued as COSV57353551; called by muse, mutect2, varscan2
- RNFT2 | c.822C>A p.T274= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as COSV57483792, COSV57489810; called by muse, mutect2, varscan2
- RP9 | c.549G>A p.E183= | Silent (SNP) | VAF 20/159 reads (13%) | catalogued as COSV51806302, COSV99778056; called by muse, mutect2, varscan2
- RYR1 | c.2520C>T p.G840= | Silent (SNP) | VAF 93/166 reads (56%) | catalogued as COSV62091771; called by muse, mutect2, varscan2
- RYR2 | c.13071C>A p.A4357= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as COSV63669974; called by muse, mutect2
- SLC22A11 | c.696G>T p.T232= | Silent (SNP) | VAF 55/108 reads (51%) | catalogued as COSV57252241; called by muse, mutect2, varscan2
- SLC27A6 | c.738T>G p.A246= | Silent (SNP) | VAF 29/186 reads (16%) | catalogued as COSV99322176; called by muse, mutect2, varscan2
- SLC6A5 | c.2379G>T p.L793= | Silent (SNP) | VAF 92/149 reads (62%) | catalogued as rs201726001, COSV54224583; called by muse, mutect2, varscan2
- SOX10 | c.624G>A p.K208= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV62806225; called by muse, mutect2, varscan2
- SPINT4 | c.120C>A p.P40= | Silent (SNP) | VAF 24/116 reads (21%) | catalogued as COSV54142486; called by muse, mutect2, varscan2
- SPTLC1 | c.9C>T p.T3= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV52763116; called by muse, mutect2, varscan2
- SSR3 | c.252C>G p.L84= | Silent (SNP) | VAF 24/115 reads (21%) | catalogued as COSV54020151; called by muse, mutect2, varscan2
- SYK | c.1617C>T p.Y539= | Silent (SNP) | VAF 43/160 reads (27%) | catalogued as rs201650753, COSV65325775, COSV65330072; called by muse, mutect2, varscan2
- TAL1 | c.957T>C p.P319= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV53745617; called by muse, mutect2, varscan2
- TCOF1 | c.3654C>A p.A1218= (on ENST00000377797 / NM_001135243.1; = p.A1141= on NM_000356.4) | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV60353406; called by muse, mutect2, varscan2
- TEX45 | c.1197G>T p.R399= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as rs1255752040, COSV64462866; called by muse, mutect2, varscan2
- TFAP2B | c.813C>T p.V271= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV53825777; called by muse, mutect2, varscan2
- THAP9 | c.1083G>A p.L361= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as COSV56355866; called by muse, mutect2, varscan2
- THEMIS2 | c.1320C>T p.Y440= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs765639848, COSV61077359; called by muse, mutect2, varscan2
- THSD7A | c.831C>A p.R277= | Silent (SNP) | VAF 38/232 reads (16%) | catalogued as rs377308966, COSV70261643; called by muse, mutect2, varscan2
- TLCD5 | c.138C>T p.L46= (on ENST00000375095 / NM_001198671.2; = p.L68= on NM_174926.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV58754704; called by muse, mutect2, varscan2
- TMEM132E | c.2322G>T p.V774= (on ENST00000321639; = p.V864= on NM_001304438.2) | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV58695331; called by muse, mutect2, varscan2
- TMEM169 | c.63C>T p.L21= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV55264512; called by muse, mutect2, varscan2
- TMTC3 | c.1776G>T p.L592= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as COSV57122704; called by muse, mutect2, varscan2
- TRIM2 | c.1311C>T p.R437= (on ENST00000437508; = p.R464= on NM_015271.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs141510470; called by muse, mutect2, varscan2
- TRPV3 | c.420G>A p.V140= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as COSV56789376; called by muse, mutect2, varscan2
- TSPAN13 | c.297G>T p.L99= | Silent (SNP) | VAF 21/180 reads (12%) | catalogued as COSV50437793; called by muse, mutect2, varscan2
- TTC23L | c.969C>T p.F323= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as COSV72205785; called by muse, mutect2, varscan2
- TTN | c.44947C>A p.R14983= (on ENST00000591111; = p.R7559= on NM_003319.4) | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV59913266, COSV59932465; called by muse, mutect2, varscan2
- TTN | c.24795A>G p.L8265= (on ENST00000591111; = p.L7338= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs1256143330, COSV59932509; called by muse, mutect2, varscan2
- UBQLN2 | c.483G>T p.S161= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV57739197; called by muse, mutect2, varscan2
- UNC13C | c.2511T>A p.S837= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV52850595; called by muse, mutect2, varscan2
- UNC5B | c.402C>T p.S134= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV58975265; called by muse, mutect2, varscan2
- UNCX | c.339C>T p.T113= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs781509694, COSV100310287, COSV60332931, COSV60333656; called by muse, mutect2, varscan2
- VN1R1 | c.180C>A p.I60= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as rs1478228184, COSV58090803, COSV58091361; called by muse, mutect2, varscan2
- ZEB1 | c.609C>T p.S203= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV58038859; called by muse, mutect2, varscan2
- ZNF391 | c.312A>T p.S104= | Silent (SNP) | VAF 18/143 reads (13%) | catalogued as COSV55121798; called by muse, mutect2, varscan2
- ZNF43 | c.426G>A p.Q142= | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as rs34211771, COSV61683217; called by muse, mutect2, varscan2
- ZNF518B | c.2853G>T p.V951= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV58721685; called by muse, mutect2, varscan2
- ZNF786 | c.924G>T p.V308= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV60275233; called by muse, mutect2, varscan2
- ZP1 | c.861C>T p.V287= | Silent (SNP) | VAF 35/220 reads (16%) | catalogued as rs1439768269, COSV53923540; called by muse, mutect2, varscan2
- ZSCAN1 | c.264C>A p.G88= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV56607854, COSV99991693; called by muse, mutect2, varscan2
- CDV3 | c.*1G>A | 3'UTR (SNP) | VAF 23/96 reads (24%) | catalogued as COSV99394152; called by muse, mutect2, varscan2
- CHCHD2P9 | n.328C>A | RNA (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- DKC1 | c.771+205C>G | Intron (SNP) | VAF 25/80 reads (31%) | catalogued as COSV101059860, COSV65776982, COSV65777037; called by muse, mutect2, varscan2
- GBA3 | c.59-8463G>T | Intron (SNP) | VAF 53/241 reads (22%) | called by muse, mutect2, varscan2
- GBA3 | c.59-8175C>G | Intron (SNP) | VAF 13/181 reads (7%) | called by muse, mutect2
- GIPR | c.633+131G>A | Intron (SNP) | VAF 6/68 reads (9%) | catalogued as rs1206620651, COSV54423126; called by muse, mutect2
- GPR141 | chr7:37741312 C>A | 3'Flank (SNP) | VAF 37/109 reads (34%) | catalogued as rs559113460, COSV100550224; called by muse, mutect2, varscan2
- HTR3E | c.68-82C>A | Intron (SNP) | VAF 101/221 reads (46%) | catalogued as COSV100093679; called by muse, mutect2, varscan2
- MIR802 | n.32C>A | RNA (SNP) | VAF 15/69 reads (22%) | called by muse, mutect2, varscan2
- MRPL4 | c.-1G>C | 5'UTR (SNP) | VAF 6/22 reads (27%) | catalogued as COSV99459751, COSV99459772; called by muse, mutect2, varscan2
- NXF5 | n.1226A>G | RNA (SNP) | VAF 38/104 reads (37%) | catalogued as rs778203810, COSV53790112; called by muse, mutect2, varscan2
- PARGP1 | n.660C>G | RNA (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- PML | c.1710+1284G>T | Intron (SNP) | VAF 38/74 reads (51%) | catalogued as rs777383825, COSV99166681; called by muse, mutect2, varscan2
- RUNDC1 | c.*2G>T | 3'UTR (SNP) | VAF 26/57 reads (46%) | catalogued as rs1473576496, COSV100865784; called by muse, mutect2, varscan2
- ZNRF2 | c.469+3996G>C | Intron (SNP) | VAF 24/156 reads (15%) | catalogued as COSV100546176, COSV59910545; called by muse, mutect2, varscan2
